Gene-level copy-number profile of tumor specimen TCGA-85-6560-01A from TCGA case TCGA-85-6560, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 59.6 years (21,768 days).
Specimen TCGA-85-6560-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.773dc6fa-8b2b-4648-976c-71ea734319b2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-6560-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/93865d54-03e2-432e-95dc-f036487706d2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 1,086; copy number 2: 29,444; copy number 3: 17,616; copy number 4: 10,545; copy number 5: 146; copy number 6: 748; copy number 7: 125; copy number 9: 62; copy number 18: 33.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-6560-01A-11D-1816-01): tumor purity 0.49, ploidy 2.72, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:25,919,499–26,251,546, 13 genes: CFTRP1, LINC01733, FAM182A, AL078587.1, AL078587.2, AL450124.1, BSNDP3, NCOR1P1, AL391119.1, AL121904.2, MIR663AHG, AL121904.1, MIR663A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,114 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:177,294,442–178,172,449, 14 genes, copy number 5: LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015, AC007953.1, AC007953.2, RNU6-1120P, AC110992.1.
- chr5:58,198–45,895,970, 710 genes, copy number 6 (broad region; genes not listed).
- chr8:38,030,534–42,171,673, 95 genes, copy number 9–18 (broad region; genes not listed).
- chr10:27,744,786–33,917,804, 116 genes, copy number 7 (broad region; genes not listed).
- chr10:34,201,979–34,202,074, 1 gene, copy number 7: Y_RNA.
- chr10:53,291,072–55,627,942, 8 genes, copy number 7 (within-gene range 2–10): AC036101.1, RNA5SP318, AL365496.1, PCDH15, RNU6-687P, AL353784.1, NEFMP1, MIR548F1.
- chr14:34,920,858–38,213,067, 74 genes, copy number 5–6 (broad region; genes not listed).
- chr14:40,630,006–41,604,988, 7 genes, copy number 6 (within-gene range 4–6): AL390800.1, LINC02315, AL391516.1, AL356596.1, AL121821.3, AL121821.2, AL121821.1.
- chr14:50,050,368–50,865,659, 28 genes, copy number 5: PDLIM1P1, AL117692.1, RN7SKP193, Y_RNA, VCPKMT, SOS2, L2HGDH, MIR4504, DMAC2L, AL359397.2, CDKL1, AL359397.1, MAP4K5, AL118556.1, Y_RNA, AL118556.2, ATL1, SNRPGP1, SAV1, RN7SL452P, AL606834.1, ZFP64P1, NIN, AL606834.2, AL133485.2, AL133485.3, AL133485.1, AL358334.1.
- chr21:42,403,447–44,106,552, 53 genes, copy number 5: UBASH3A, RNU6-1149P, RSPH1, SLC37A1, AP001625.3, AP001625.1, AP001625.2, LINC01671, AP001626.1, PDE9A, PDE9A-AS1, LINC01668, AP001628.2, AP001628.1, WDR4, NDUFV3, ERVH48-1, MIR5692B, AP001630.1, PKNOX1, CBS, U2AF1, AP001631.2, MRPL51P2, FRGCA, AP001631.1, CRYAA, LINC00322, LINC01679, AP001046.1, SIK1, LINC00319, LINC00313, AP001048.1, HSF2BP, RPL31P1, H2BS1, MIR6070, RRP1B, PDXK, AP001052.1, AP001053.1, CSTB, TMEM97P1, RRP1, AATBC, MYL6P1, AGPAT3, RNU6-859P, AP001054.1, RNU6-1150P, TRAPPC10, H2AZP1.
- chr21:46,324,141–46,445,769, 1 gene, copy number 5 (within-gene range 3–5): PCNT.
- chr21:46,420,553–46,665,124, 7 genes, copy number 5: RPL18AP2, DIP2A, DIP2A-IT1, RNU6-396P, S100B, PRMT2, DSTNP1.

Autosomal genes at a single copy (total copy number 1): 1,086. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
